Somatic mutation profile of tumor specimen TCGA-ET-A3BX-01A (aliquot TCGA-ET-A3BX-01A-11D-A19J-08) from TCGA case TCGA-ET-A3BX, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 24.1 years (8,791 days).
Specimen TCGA-ET-A3BX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8860196b-3f1b-4075-b0ed-46f26de75f85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3BX-10A (Blood Derived Normal), aliquot TCGA-ET-A3BX-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d378dbd1-ff15-4e41-836c-749fd2fabe8d

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FLG2 | c.1117G>A p.G373S | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV66170085; called by muse, mutect2, varscan2
- MIA2 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.26); catalogued as COSV54495575; called by muse, mutect2, varscan2
- MOB1A | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV68517617; called by muse, mutect2, varscan2
- TRAPPC5 | c.485C>G p.A162G | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV58040326; called by muse, mutect2, varscan2
- USP32 | c.3002T>C p.V1001A | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs570294099, COSV56264322; called by muse, mutect2, varscan2
- VPS13D | c.7790C>G p.A2597G | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.12); catalogued as COSV50646837, COSV50651308; called by muse, mutect2, varscan2
